Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4QL, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4QL-01A (Primary Tumor).

Gross Description: There is a part of the stomach with the saucer-like tumor up to 10.00 cm in size, with invasion into the fatty tissue. Lymph nodes are up to 1 cm (suspicion of metastases). Omentum is hyperemic.

Microscopic Description: Adenocarcinoma of the stomach, G-2, with superficial ulceration and invasion into the perigastric fatty tissue. Four of five examined lymph nodes along the lesser curvature and five examined lymph nodes along the greater curvature demonstrated metastases. Omentum is hyperemic.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Perigastric fat, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Original records read pT3N3aM0.

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Antrum

Tumor size: 0 x 0 x 10 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Other - Perigastric fat

Lymph nodes: 9/10 positive for metastasis (Greater and lesser curvature 9/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: Stomach, antrum C16.3

hw
10/23/12

Source: NCI Genomic Data Commons file acb3fba3-06d3-4af1-b4b6-293bcbc9af0a (TCGA-BR-A4QL.E2FF83BD-C0E2-439E-ABF4-BCFC4008D323.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).